Surgical pathology report (de-identified scan), TCGA case TCGA-HS-A5NA, project TCGA-SARC (Sarcoma), tissue source site Ontario Institute for Cancer Research (OICR), specimen TCGA-HS-A5NA-01A (Primary Tumor).

Sample Number

Sample Type TUMOUR

Diagnosis	leiomyosarcoma
Year of Sample Collection	
Age at Sample Collection (yrs)	
Days to Procedure Date	
Days to Diagnosis	
Type of Procedure	RESECT
Site of Tissue/Primary (Histology)	Uterus
Tumour Size (cm)	21
Histology	leiomyosarcoma
Grade/Differentiation	X
Pathological T	N/A
Pathological N	N/A
Clinical M	MP
Histology Comments	Histologic type: Leiomyosarcoma

Sample Number

Sample Type BUFFY

Year of Sample Collection	
Age at Sample Collection (yrs)	
Days to Procedure Date	
Days to Diagnosis	

ICD-O-3

Leiomyosarcoma NOS 8890/3

Site Uterus NOS C55.9

QID 2/11/13

Source: NCI Genomic Data Commons file c284f25d-f904-4607-9971-c7ed08e4582b (TCGA-HS-A5NA.4589796C-4F18-44BC-8EC9-D31D8190BC18.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).